Somatic mutation profile of tumor specimen TCGA-CM-6680-01A (aliquot TCGA-CM-6680-01A-11D-1835-10) from TCGA case TCGA-CM-6680, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 78.6 years (28,701 days).
Specimen TCGA-CM-6680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a4a68e6-1de8-4173-89ab-68d3e748fd5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6680-10A (Blood Derived Normal), aliquot TCGA-CM-6680-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc827c6a-695b-4d0f-9106-b0fe6c0a1113

The open-access MAF lists 100 somatic variants for this specimen: 69 protein-altering or splice-affecting, 31 silent.
By variant classification: Missense Mutation 53, Silent 31, Frame Shift Del 9, Nonsense Mutation 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 70/257 reads (27%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4741del p.S1581Lfs*69 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as rs886039682; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 76/234 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMAD4 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 45/66 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684573, COSV61686129, COSV61697475; called by muse, mutect2, varscan2
- ADAMDEC1 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs1254589259, COSV56474629; called by muse, mutect2, varscan2
- ATP12A | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752142201, COSV54520393; called by muse, mutect2, varscan2
- CACNA1B | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs754545679, COSV53119020; called by muse, mutect2, varscan2
- CADPS | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs151301388; called by muse, mutect2, varscan2
- CAMKK1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1253533984, COSV99340297, COSV99340316; called by muse, mutect2, varscan2
- CCDC3 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs754059035, COSV66558962; called by muse, mutect2, varscan2
- CD109 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs371377745; called by muse, mutect2, varscan2
- CDH10 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV52577289; called by muse, mutect2, varscan2
- CELSR2 | c.2558C>A p.T853N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54768758; called by muse, mutect2, varscan2
- CLCA4 | c.208dup p.R70Kfs*13 | Frame Shift Ins (INS) | VAF 56/188 reads (30%) | catalogued as rs148031684; called by mutect2, pindel, varscan2
- CTNNA2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV63555227; called by muse, mutect2
- CTRC | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs768414501, COSV65621291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCDC1 | c.3772G>T p.A1258S (on ENST00000597505 / NM_001367979.1; = p.A365S on NM_020869.3) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.117); catalogued as COSV57998220; called by muse, mutect2, varscan2
- FAT4 | c.11309G>A p.R3770Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs540725305, COSV58683662; called by muse, mutect2, varscan2
- FOXO4 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs868275368, COSV58574959; called by muse, mutect2, varscan2
- GJA8 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202852786, COSV53788305, COSV53788867; called by muse, mutect2, varscan2
- GJA8 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.354); catalogued as rs782056871, COSV53788320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPBP1L1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51967897; called by muse, mutect2, varscan2
- GPC4 | c.1272G>A p.W424* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV63697362; called by muse, mutect2, varscan2
- GPR32 | c.552A>C p.K184N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as COSV99567228; called by muse, mutect2, varscan2
- GRM3 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862571; called by muse, mutect2, varscan2
- HDC | c.487A>C p.K163Q | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV51068822; called by muse, mutect2, varscan2
- HMCN1 | c.6071T>C p.V2024A | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.509); catalogued as COSV99629730; called by muse, mutect2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 26/151 reads (17%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- LAMB2 | c.2057G>A p.G686D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV59731916; called by muse, mutect2, varscan2
- LCK | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV60739199, COSV60739998; called by muse, mutect2
- LENG8 | c.1840G>A p.G614S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV100418081; called by muse, mutect2
- LYZL1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs766725731, COSV64966156; called by muse, mutect2, varscan2
- MAG | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200718920, COSV62699130; called by muse, mutect2, varscan2
- MAP3K13 | c.1549C>T p.R517* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as rs56408536, COSV53985652; called by muse, mutect2, varscan2
- MARS1 | c.212del p.L71Cfs*33 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | catalogued as rs751080704; called by mutect2, varscan2
- MATN1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV65650298; called by muse, mutect2, varscan2
- MIPEP | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs746768958, COSV66300069; called by muse, mutect2, varscan2
- MYCT1 | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV65891021; called by muse, mutect2, varscan2
- NFATC2 | c.2579A>G p.Y860C | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV101044156; called by muse, mutect2, varscan2
- NTNG2 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs776635613, COSV62365570, COSV62368289; called by muse, mutect2, varscan2
- OGDHL | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs772306801, COSV65101628; called by muse, mutect2, varscan2
- PAG1 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs372766293; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDH17 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as rs1293017384, COSV64972900; called by muse, mutect2, varscan2
- PLPPR5 | c.937C>A p.H313N (on ENST00000263177 / NM_001037317.2; = p.H308N on NM_001010861.3) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV54170703; called by muse, mutect2, varscan2
- PLXNA2 | c.4142G>A p.R1381H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745341868, COSV65438803; called by muse, mutect2, varscan2
- PRDM15 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as rs757478169, COSV99520139; called by muse, mutect2, varscan2
- PTCHD1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1354399604, COSV65059491; called by muse, mutect2, varscan2
- PTPRN | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs372873328; called by muse, mutect2, varscan2
- R3HDM4 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV64292887; called by muse, mutect2, varscan2
- RBM27 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as rs1171449724, COSV54588521; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 20/165 reads (12%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RPN1 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV56189449; called by muse, mutect2
- RUFY4 | c.1275del p.E426Rfs*11 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | catalogued as COSV60246736; called by mutect2, pindel, varscan2
- SDSL | c.407G>T p.W136L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV61884379; called by muse, mutect2, varscan2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs747319777; called by mutect2, varscan2
- SORBS2 | c.1736T>C p.I579T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV52994980; called by muse, mutect2, varscan2
- SUPT6H | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV58925777, COSV58927562; called by muse, mutect2, varscan2
- TEAD3 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV58816157; called by muse, mutect2, varscan2
- TMEM132D | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369491698; called by muse, mutect2, varscan2
- TNFRSF10A | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99646213; called by muse, mutect2, varscan2
- TUT4 | c.3209A>G p.D1070G | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99932386; called by muse, mutect2, varscan2
- UNC79 | c.4952C>T p.T1651M (on ENST00000393151 / NM_001346218.2; = p.T1474M on NM_020818.5) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs201026597; called by muse, mutect2, varscan2
- USP9X | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV61067329; called by muse, mutect2, varscan2
- VMP1 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV51865741, COSV99230940; called by muse, mutect2, varscan2
- ELAPOR2 | c.3022del p.A1008Qfs*14 (on ENST00000450689 / NM_001142749.3; = p.A841Qfs*14 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 45/147 reads (31%) | called by mutect2, pindel, varscan2
- H2AC16 | c.367_368del p.H124Pfs*11 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | called by pindel, varscan2
- SOX9 | c.641_653del p.S214* | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, varscan2
- ADCY8 | c.2226C>T p.T742= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV99652497; called by muse, mutect2, varscan2
- ADGRA2 | c.3018G>A p.P1006= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1003326848, COSV55103073; called by muse, mutect2, varscan2
- ADGRV1 | c.6096G>A p.A2032= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs1163484369, COSV67981217; called by muse, mutect2, varscan2
- ANOS1 | c.1653T>C p.P551= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as COSV99390915; called by muse, mutect2, varscan2
- CFAP54 | c.5604C>T p.D1868= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs747088881, COSV100733185; called by muse, mutect2, varscan2
- DUSP26 | c.363G>A p.S121= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs138833176; called by muse, mutect2, varscan2
- ELMO2 | c.633A>T p.I211= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV51682082; called by muse, mutect2, varscan2
- ENTHD1 | c.183C>G p.L61= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV57318459; called by muse, mutect2, varscan2
- FAM169A | c.46T>C p.L16= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs572149205, COSV100998355; called by muse, mutect2, varscan2
- FOXD4L4 | c.279G>T p.P93= | Silent (SNP) | VAF 104/348 reads (30%) | called by muse, varscan2
- GRIK2 | c.1857C>A p.L619= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV59721500; called by muse, mutect2, varscan2
- GRIN2A | c.3240C>T p.H1080= | Silent (SNP) | VAF 66/219 reads (30%) | catalogued as COSV58026353; called by muse, mutect2, varscan2
- H3C8 | c.399G>A p.G133= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV59952815; called by muse, mutect2, varscan2
- IP6K1 | c.1041G>A p.E347= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV57695129; called by muse, mutect2, varscan2
- LBHD1 | c.441C>T p.N147= (on ENST00000431002 / NM_001367940.1; = p.N121= on NM_024099.3) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs779292143, COSV63472781; called by muse, mutect2, varscan2
- MYBPC1 | c.1191A>G p.K397= (on ENST00000550270 / NM_206820.2; = p.K422= on NM_002465.4) | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV62251910, COSV62253602; called by muse, mutect2, varscan2
- NR2F6 | c.1086G>A p.A362= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs749742648, COSV52243141; called by muse, mutect2, varscan2
- P2RY12 | c.303C>T p.S101= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs778319065, COSV56393011; called by muse, mutect2, varscan2
- PCDHA10 | c.1179G>A p.P393= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs148283153, COSV100246875, COSV56486673; called by muse, mutect2, varscan2
- PCDHGA3 | c.2262C>T p.S754= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV53918988; called by muse, mutect2, varscan2
- PIP4P2 | c.315C>A p.L105= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV53438013; called by muse, mutect2, varscan2
- PLCE1 | c.228G>A p.A76= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs376238435; called by muse, mutect2, varscan2
- RELN | c.6192C>T p.H2064= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs764737797, COSV58992620; called by muse, mutect2, varscan2
- SLC25A53 | c.339C>A p.T113= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV62458646; called by muse, mutect2, varscan2
- SSX3 | c.402C>T p.N134= | Silent (SNP) | VAF 138/335 reads (41%) | catalogued as rs782355046, COSV53643531, COSV53645573; called by muse, mutect2, varscan2
- TMC6 | c.1176G>A p.T392= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs139523538; called by muse, mutect2
- TRAF6 | c.1194G>A p.P398= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs751475632, COSV61922186; called by muse, mutect2, varscan2
- TRIM3 | c.291C>T p.H97= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV61983421; called by muse, mutect2, varscan2
- UNC5C | c.1176G>A p.A392= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as rs755116229, COSV101497915; called by muse, mutect2, varscan2
- USP54 | c.4407C>T p.L1469= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs764656996, COSV100357168; called by muse, mutect2, varscan2
- ZMYND15 | c.1293C>T p.R431= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs147604131; called by muse, mutect2, varscan2
